Somatic mutation profile of tumor specimen TCGA-C5-A2M1-01A (aliquot TCGA-C5-A2M1-01A-11D-A18J-09) from TCGA case TCGA-C5-A2M1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 37.9 years (13,835 days).
Specimen TCGA-C5-A2M1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 745ab5f3-3fff-4ae7-bb6e-c4ed16dbf33c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A2M1-10A (Blood Derived Normal), aliquot TCGA-C5-A2M1-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c94fd23-5b26-4c8a-a8cd-1cf0ba0ca20a

The open-access MAF lists 102 somatic variants for this specimen: 77 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 24, Nonsense Mutation 6, Frame Shift Del 2, In Frame Del 2, Frame Shift Ins 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 35/63 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSM5 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs988151353, COSV59373414; called by muse, mutect2, varscan2
- ADAMDEC1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs1351755384, COSV99835912; called by muse, mutect2, varscan2
- ADGRA2 | c.1404G>C p.Q468H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.923); catalogued as rs1411987220; called by muse, mutect2, varscan2
- ANK2 | c.9820C>A p.P3274T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1359116496, COSV52158549; called by muse, mutect2
- APOBEC3G | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs746526466; called by muse, mutect2, varscan2
- CAMSAP2 | c.2766G>A p.M922I (on ENST00000236925 / NM_001297707.2; = p.M911I on NM_203459.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs767246605, COSV52667325; called by muse, varscan2
- CNTN4 | c.2620C>T p.H874Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61872581; called by muse, mutect2, varscan2
- DSP | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1057522287, COSV65796826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFLAM | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100380536; called by muse, mutect2
- FAM13B | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV50374346; called by muse, mutect2, varscan2
- GALNT1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52452143; called by muse, mutect2, varscan2
- GRIPAP1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64552337; called by muse, mutect2, varscan2
- JAKMIP1 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557871910, COSV101290894; called by muse, mutect2, varscan2
- KALRN | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs767151194; called by muse, mutect2, varscan2
- KCNH8 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60464301; called by muse, mutect2, varscan2
- KLF5 | c.336T>G p.Y112* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100890577, COSV66615171; called by muse, mutect2
- LRSAM1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100032032; called by muse, mutect2, varscan2
- MEOX2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100012147; called by muse, mutect2, varscan2
- MICALL2 | c.1910C>A p.T637N | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as rs374682289; called by muse, mutect2, varscan2
- NAV3 | c.3750G>T p.R1250S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57102242; called by muse, mutect2
- PHLPP1 | c.4861C>T p.R1621W | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs748532615; called by muse, mutect2, varscan2
- POLN | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs773856265; called by muse, varscan2
- PSD | c.2467C>A p.L823M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50059806; called by muse, mutect2, varscan2
- RUVBL1 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs758610032; called by muse, mutect2, varscan2
- SBNO2 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs751771586; called by muse, mutect2, varscan2
- TEX2 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs782108981, COSV99367238; called by muse, mutect2, varscan2
- TMEM175 | c.1262C>A p.A421D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53281610; called by muse, mutect2, varscan2
- USP7 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as rs1350062498; called by muse, mutect2, varscan2
- VCAN | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as rs1428665148, COSV54103669; called by muse, mutect2, varscan2
- ZNF230 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as rs1224421309; called by muse, mutect2, varscan2
- ADGRG4 | c.5494T>A p.S1832T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- AIF1 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALOX12B | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAIAP2L1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CENPF | c.7564G>A p.E2522K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CNKSR2 | c.220T>C p.C74R | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CNOT8 | c.107_111dup p.A38Ifs*23 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- FGFRL1 | c.1210_1212del p.K404del | In Frame Del (DEL) | VAF 18/73 reads (25%) | called by pindel, varscan2
- GFM1 | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GFRA2 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- GZMM | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- H3C3 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HIVEP2 | c.5749G>C p.D1917H | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- KRTAP2-1 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- LANCL2 | c.1344G>C p.K448N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MERTK | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 82/99 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH9 | c.4606_4608del p.E1536del | In Frame Del (DEL) | VAF 22/73 reads (30%) | called by pindel, varscan2
- NCKIPSD | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.259); called by muse, mutect2
- NIPBL | c.4021A>T p.K1341* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- NOX3 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NPAP1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- OR10K1 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OR11L1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD5 | c.1433C>A p.P478Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PCSK9 | c.29_30insAG p.W10* | Nonsense Mutation (INS) | VAF 37/111 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R3 | c.1010C>G p.A337G | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD1 | c.8952C>G p.S2984R | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PRICKLE2 | c.1308C>A p.S436R (on ENST00000295902; = p.S380R on NM_198859.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPRD2 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SAP130 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SH2D7 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHLD2 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLC6A8 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- SPRY3 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK32B | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYMPK | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAS1R3 | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, varscan2
- THADA | c.4262_4280del p.K1421Tfs*6 | Frame Shift Del (DEL) | VAF 47/87 reads (54%) | called by mutect2, pindel, varscan2
- TMC6 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- TNXB | c.7644del p.I2549Sfs*8 (on ENST00000647633; = p.I2302Sfs*8 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- VANGL2 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- VAV2 | c.1632C>G p.L544= (on ENST00000371850 / NM_001134398.2; = p.L534= on NM_003371.4) | Splice Region (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- VAV3 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2
- WFIKKN1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF257 | c.514A>T p.T172S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB4 | c.303G>A p.S101= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs886044650, COSV55943119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC006059.2 | c.1326G>C p.L442= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV59609108; called by muse, mutect2, varscan2
- BAX | c.432C>T p.L144= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV53168963; called by mutect2, varscan2
- C2CD6 | c.1871G>A p.*624= | Silent (SNP) | VAF 39/58 reads (67%) | called by muse, mutect2, varscan2
- CASP8 | c.282C>T p.G94= | Silent (SNP) | VAF 44/70 reads (63%) | catalogued as COSV51849935; called by muse, mutect2, varscan2
- CDH23 | c.3307C>T p.L1103= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs113714164; called by muse, mutect2, varscan2
- COL4A2 | c.4068G>T p.G1356= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- DAPK1 | c.2046G>A p.Q682= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100802034; called by muse, mutect2, varscan2
- EMX2 | c.30C>T p.F10= | Silent (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- EXOC3L2 | c.1596G>A p.E532= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs773236763; called by muse, mutect2, varscan2
- FAT4 | c.10152A>G p.R3384= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1183797577, COSV100630350; called by muse, mutect2, varscan2
- FYCO1 | c.1524C>A p.V508= | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- GP1BA | c.1891C>T p.L631= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as rs748482404; called by muse, mutect2, varscan2
- GPM6A | c.817C>A p.R273= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV54554724, COSV99704832; called by muse, mutect2, varscan2
- GPR132 | c.768C>G p.A256= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV61677856; called by muse, mutect2, varscan2
- KCNJ4 | c.843G>A p.S281= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs367619896, COSV100341227; called by muse, mutect2, varscan2
- NDE1 | c.726G>A p.G242= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs587783869, COSV100707256; ClinVar: likely benign; called by muse, mutect2, varscan2
- NIPBL | c.4020T>A p.T1340= | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- NLGN4X | c.1506C>A p.I502= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV52006407; called by muse, mutect2, varscan2
- PKHD1 | c.11493C>T p.V3831= | Silent (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.477G>A p.E159= | Silent (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- SNRPD1 | c.243G>C p.V81= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- SPTLC1 | c.444G>A p.L148= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- ZBTB18 | c.699G>A p.S233= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs761237988, COSV62397938; called by muse, mutect2, varscan2
- SPECC1L | c.-2G>C | 5'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
